Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3AA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3AA-06A (Metastatic).

[page 1 of 2]
REPORT COPY
from Medical Abstract

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axilla C17.3
lw 9/21/11

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries:

REQUESTING DR :
VERIFIED BY :

SPECIMEN DATE
ACCESSION :

REPORTED BY

Reported by: Dr

Previous Lab. Ref:

CLINICAL INFORMATION

Unknown primary. Palp (R) axilla mass - FNA -> met melanoma.

OPERATION/NATURE OF SPEC

(R) axillary dissection to level III. Separate apical tissue.

MACROSCOPIC DESCRIPTION

Two specimens were received.

I. "Right axillary contents". An irregular fragment of fat, 120 x 85 x 40mm with an attached ragged piece of skeletal muscle 100 x 35 x 25mm. A large tumour mass could be felt within the fat and a portion of it was removed fresh for the . In the fixed state the tumour mass is 40 x 30 x 28mm and appears macroscopically to be a lymph node occupied by tumour. The cut surface of the ?node is homogeneously soft and cream.

A. One representative section of tumour mass/lymph node.

The fat was examined for lymph nodes.

- B. 3 nodes.
- C. 1 node bisected.
- D. 3 nodes.
- E. 1 node bisected.
- F. 1 node bisected.
- G. 1 node bisected.
- H. 2 nodes.
- J. 2 nodes.
- K. 3 nodes.
- L. 3 nodes.

II. "Apical node tissue right axilla". A piece of soft, fatty tissue 23 x 14 x 8mm, containing a ?lymph node 8 x 5 x 4mm. All embedded.

[page 2 of 2]
REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries :

REQUESTING DR :
Verified by :

SPECIMEN DATE
ACCESSION

MICROSCOPIC DESCRIPTION

I. "Right axillary contents". Metastatic malignant melanoma virtually replaces one node (A) with no perinodal spread. The other twenty nodes show no evidence of malignancy.

II. "Apical node tissue right axilla". Lymph node with no evidence of malignancy.

SNOMED CODES

Lymph node - malignant melanoma - metastatic.
Haematopathology resection

T-08000

***** END OF ACCESSION *****

Source: NCI Genomic Data Commons file 6e6e420d-e5a8-4000-8b35-9618e147239f (TCGA-EE-A3AA.8EEE31CE-9D42-4D14-95C3-0AB0B00CE41B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).